Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4994, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4994-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with left renal mass.

TCGA-BP-4994

Specimens Submitted:

1: Kidney, left renal tumor, partial nephrectomy

DIAGNOSIS:

1. Kidney, left renal tumor, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 2.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1.) The specimen is received fresh for frozen section, labeled "left renal tumor". It consists of a 4.5 x 4.0 x 2.4 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a single well-circumscribed mass measuring 2.5 x 2.0 x 2.0 cm with bulging homogeneous tan lobulated cut surfaces interrupted by fibrous bands. The clearance from the resection margin is 0.1 cm. The surrounding renal parenchyma appears grossly normal. A representative section of the nearest margin is submitted for frozen section diagnosis. A portion of tumor is submitted for TPS. Representatively submitted.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - representative sections of kidney

Summary of Sections:

Part 1: Kidney, left renal tumor, partial nephrectomy

Block	Sect. Site	PCs
1	FSC	1
1	M	1
1	RS	1
3	T	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: CORTICAL RENAL NEOPLASM ON REPRESENTATIVE SECTION, INKED MARGIN NEGATIVE
PERMANENT DIAGNOSIS:

Source: NCI Genomic Data Commons file 628e5747-e1ce-40c9-b97a-f9bcf1099399 (TCGA-BP-4994.ABDB9F72-F96E-49D8-A846-3632FC01D438.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).